Gene-level copy-number profile of tumor specimen TCGA-BG-A3EW-01A from TCGA case TCGA-BG-A3EW, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage III; Tumor grade: G3; Age at diagnosis: 62.2 years (22,705 days).
Specimen TCGA-BG-A3EW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.f1d7b569-d44b-42be-b570-910c78207803.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BG-A3EW-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cb73df21-8cac-46d9-8f97-d17ce6549110

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7; copy number 2: 57,142; copy number 3: 62; copy number 4: 4; copy number 5: 2,604.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BG-A3EW-01A-11D-A227-01): tumor purity 0.88, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,604 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
